Gene-level copy-number profile of tumor specimen TCGA-EE-A2MS-06A from TCGA case TCGA-EE-A2MS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.6 years (29,791 days).
Specimen TCGA-EE-A2MS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.86549b2e-c0b5-4a58-9e78-39876026bffb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2MS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f5bc923-aadb-4d2d-af7d-95d72c888614

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,090; copy number 2: 17,455; copy number 3: 20,546; copy number 4: 11,460; copy number 5: 2,352; copy number 6: 3,119; copy number 7: 445; copy number 8: 32; copy number 9: 40; copy number 10: 1; copy number 11: 176; copy number 12: 42; copy number 13: 53; copy number 14: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2MS-06A-11D-A191-01): tumor purity 0.82, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:87,160,103–87,240,314, 3 genes: KLHL8, AC092658.1, GAPDHP60.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 791 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,459,848–60,702,010, 8 genes, copy number 7: SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1.
- chr6:54,840,118–54,945,099, 3 genes, copy number 7: AL512363.1, FAM83B, AL049555.1.
- chr6:56,276,529–63,779,336, 62 genes, copy number 7 (broad region; genes not listed).
- chr6:63,797,189–64,631,682, 5 genes, copy number 7: AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2.
- chr7:9,614,978–16,784,536, 71 genes, copy number 7 (broad region; genes not listed).
- chr7:35,496,021–35,510,263, 1 gene, copy number 10: AC007652.1.
- chr7:51,382,284–54,621,131, 35 genes, copy number 7: CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P.
- chr7:77,310,751–97,599,260, 239 genes, copy number 7 (broad region; genes not listed).
- chr7:153,144,313–154,894,285, 11 genes, copy number 7 (within-gene range 6–7): AC079809.1, LINC01287, AC073236.1, PAXBP1P1, AC005998.1, DPP6, AC005588.1, AC006019.3, AC006019.1, AC006019.2, AC024730.1.
- chr12:48,231,098–48,765,790, 28 genes, copy number 13 (within-gene range 4–13): AC024257.1, AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20, AC089987.1, OR8S1, OR5BS1P, LALBA, OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B, CCNT1, TEX49.
- chr12:54,948,015–55,900,618, 56 genes, copy number 11: TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76, AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P, OR6C4, OR2AP1, OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B, ITGA7, AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3, GSTP1P1.
- chr12:56,202,179–57,984,761, 113 genes, copy number 11 (broad region; genes not listed).
- chr12:58,544,124–59,130,875, 7 genes, copy number 11: AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1.
- chr12:61,775,923–61,880,772, 2 genes, copy number 14: RPL21P104, KRT8P19.
- chr12:65,824,460–67,442,559, 31 genes, copy number 9–13: HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420.
- chr12:68,674,371–72,670,758, 74 genes, copy number 8–12 (within-gene range 6–12) (broad region; genes not listed).
- chr12:75,334,670–76,757,914, 34 genes, copy number 9: GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1.
- chr15:58,856,831–59,133,250, 11 genes, copy number 7: AC090515.4, ZNF444P1, RNF111, AC090515.1, SLTM, AC025918.1, AC025918.2, AC092757.1, CCNB2, AC092757.3, AC092757.2.

Autosomal genes at a single copy (total copy number 1): 4,090. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
